Surgical pathology report (de-identified scan), TCGA case TCGA-56-8622, project TCGA-LUSC (Lung Squamous Cell Carcinoma), tissue source site International Genomics Consortium, specimen TCGA-56-8622-01A (Primary Tumor).

[page 1 of 3]
Results

GROSS AND MICROSCOPIC SURGICAL PANEL

Case# [REDACTED] Final Report

DIAGNOSIS

A) BONE, RIGHT SIXTH RIB:

1. Rib (gross examination)
2. Marrow with trilineage maturation
3. Negative for malignancy

B) LUNG, RIGHT LOWER LOBE, LOBECTOMY:

1. Squamous cell carcinoma, moderately differentiated, 3.5 cm
2. Tumor is confined to the lung, negative for pleural involvement by tumor
3. Surgical margins are negative for tumor
4. Negative for lymphatic/vascular invasion by tumor
5. One intralobar (N1) lymph node, negative for metastasis (0/1)
6. Two hilar (N1) lymph nodes, negative for metastasis (0/2)
7. Please see lung cancer staging parameters below

C) LYMPH NODE, STATION 7 N2, BIOPSY: One lymph node negative for metastasis (0/1)

LUNG CANCER STAGING PARAMETERS***

Case number: [REDACTED] Patient name: [REDACTED]

Final TNM: pT2aN0M0

stage: IB

MACROSCOPIC

SPECIMEN TYPE

Lobectomy

TUMOR SITE

Right Lung-Lower Lobe

TUMOR SIZE

Greatest dimension is 3.5 cm

TUMOR FOCALITY

Unifocal

MICROSCOPIC

HISTOLOGIC TYPE

Squamous cell carcinoma

HISTOLOGICAL GRADE

G2: (moderately differentiated) of G4

VISCERAL PLEURAL INVASION

Not identified

LYMPHATIC VASCULAR INVASION

Absent

TREATMENT EFFECT

Not applicable

[page 2 of 3]
MARGINS

Uninvolved by tumor

PATHOLOGIC STAGING

EXTENT OF INVASION

pT2a. (Tumor greater than 3 cm, but 5 cm or less in greatest dimension surrounded by lung or visceral pleura, without bronchoscopic evidence of invasion more proximal than the lobar bronchus (ie, not in the main bronchus); or Tumor 5 cm or less in greatest dimension with any of the following features of extent: involves main bronchus, 2 cm or more distal to the carina; invades the visceral pleura; associated with atelectasis or obstructive pneumonitis that extends to the hilar region but does not involve the entire lung)

REGIONAL LYMPH NODES

pN0. (No regional lymph node metastasis)

Total nodes: 4

Total positive nodes: 0

N1 nodes: 3

N1 positive nodes: 0

N2 nodes: 1

N2 positive nodes: 0

N2 sites sampled:

Station 7: Subcarinal nodes

DISTANT METASTASIS

pM0. (No distant metastasis)

PATHOLOGIC STAGE Summary

Final TNM: pT2aN0M0

Stage: IB

** The pathologic stage presumes no distant metastasis.

LUNG ANCILLARY TESTING PROTOCOL

Case number: Patient name:

HISTOLOGIC TYPE

Squamous cell carcinoma

STAGE IV STATUS

Stage IV status is undetermined

TISSUE BLOCK AVAILABLE FOR ANCILLARY TESTING

BFS2, B3-6

COMMENT

This patient's sample does not meet criteria* for reflex EGFR and ALK testing. No fresh tissue is available for ancillary testing. The block identified above will be stored in pathology for 10 years for possible future ancillary testing. Please call for any ancillary testing requests.

Lung Cancer Committee EGFR and ALK reflex testing criteria:

Stage IV disease (histologically proven or clinically suspicious)

Adenocarcinoma or TTF-1 positive adenosquamous cell carcinoma.

Attending Pathologist:

CLINICAL INFORMATION

The patient is status-post heart transplant in 2005. CT identified "non-caseating granulomas" in the right lung measuring 3 x 3 cm. Two previous FNAs were attempted on the mass. One identified noncaseating granulomas; and the other identified normal lung parenchyma. Three subsequent hilar lymph node biopsies identified benign lymphoid material.

[page 3 of 3]
[REDACTED]

SPECIMEN/GROSS DESCRIPTION

A) SOURCE: Right sixth rib bone

Received fresh and labeled "right sixth rib" and consists of a portion of rib measuring 6.5 x 1.5 x 0.6 cm with scant fragments of attached muscle with cautery artifact. No surface lesions are identified. Representative marrow is extracted and submitted into one cassette.

B) SOURCE: Right lower lobe of lung

The specimen consists of a portion of lung weighing 260 gm and measuring 18.5 x 13 x 3 cm. A single staple line is present measuring 7 cm in length; and a stitch on the contralateral aspect of the specimen demarcates the bronchial margin. The specimen is received partially disrupted adjacent to the staple line. In the area of disruption, a firm, tan-white round and well-demarcated mass measuring 3.5 x 3.0 x 2.5 cm is identified, and comes to within 0.1 cm of the pleural surface. The pleural surface is inked blue. The tumor is located 4.5 cm from the bronchial margin.

INTRAOPERATIVE PATHOLOGY CONSULTATION: "Bronchial margin negative" is rendered by [REDACTED]

INTRAOPERATIVE PATHOLOGY CONSULTATION WITH FROZEN SECTION: "Tumor nodule - non-small cell carcinoma, favor squamous cell" is rendered by [REDACTED]

The staple line is removed and inked orange. The tumor is 0.4 cm from the staple line after its removal. Subpleural anthracotic pigment is minimal. Two hilar lymph nodes are identified and submitted entirely. The remainder of the specimen is completely sectioned revealing tan-pink crepitant parenchyma without additional lesions.

Tissue is obtained for possible ancillary studies.

Sections are submitted into nine cassettes as follows:

FS1. Bronchial margin

FS2. Representative tumor

B3. Tumor with overlying inked pleura

B4. Tumor towards bronchial margin

B5. Tumor with inked staple line margin

B6. Tumor with uninvolved parenchyma

B7. Uninvolved normal parenchyma with intraparenchymal lymph node

B8. Bronchial pseudo margin (true bronchial margin submitted for frozen section)

B9. Vascular margin with two hilar lymph nodes, each bisected

[REDACTED]

C) SOURCE: Station 7 lymph node

Labeled "station 7 lymph node" is a 2.8 x 2.1 x 2 cm lobulated maroon-brown lymph node with several attached metal clips. Cut surfaces are maroon-black and without discrete suspicious foci. Entirely submitted in four cassettes.

This case is accessioned in [REDACTED]

Gross dictation by [REDACTED]

MICROSCOPIC

A-C) The microscopic appearance substantiates the diagnosis.

[REDACTED]

[REDACTED]

Source: NCI Genomic Data Commons file 4569f7bb-18dd-428b-b09b-a7a27eb969d2 (TCGA-56-8622.4366E2BC-8DED-4969-A3BD-18AF96DE43A6.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).